MMRF case MMRF_1089 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7d8b949a-9669-418e-8e7b-7846089775ce

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.3 years (22,405 days); ISS stage: III; Days to last known disease status: 1,333 days (3.6 years); Days to last follow up: 1,333 days (3.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 547 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 547 days (1.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,333.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -26 (ECOG 0): M Protein 3.85 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 331 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.597 mg/dL; Immunoglobulin G 48.9 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 6.37 µg/mL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 190 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.2 mmol/L; Albumin 30 g/L; Total Protein 10.3 g/dL; Glucose 12 mmol/L; C-Reactive Protein 15.6 mg/dL.
- Day 149 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.863 mg/dL; Immunoglobulin G 7.49 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.63 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 5.18 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 10.1 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 143 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 7.87 mmol/L.
- Day 191: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 9.69 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.57 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.8 g/dL; Glucose 5.72 mmol/L.
- Day 363: M Protein 0 g/dL; Hemoglobin 9.49 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.4 mmol/L; Albumin 48 g/L; Total Protein 7.8 g/dL; Glucose 6.88 mmol/L.
- Day 540: Creatinine 137 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Glucose 7.65 mmol/L.
- Day 716 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.616 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.296 mg/dL; Immunoglobulin G 17.8 g/L; Immunoglobulin A 3.02 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Glucose 7.76 mmol/L.
- Day 776 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.552 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.247 mg/dL; Immunoglobulin G 17.7 g/L; Immunoglobulin A 2.74 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.8 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 6.77 mmol/L.
- Day 891: Serum Free Immunoglobulin Light Chain, Kappa 0.537 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.252 mg/dL; Immunoglobulin G 18.2 g/L; Immunoglobulin A 3.3 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 141 µmol/L; Glucose 6.05 mmol/L.
- Day 1,259: Lactate Dehydrogenase 4.55 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 95.1 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 7.7 g/dL; Glucose 8.03 mmol/L.

Other clinical attributes
- Day -26: Weight: 87 kg; Height: 167 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1089_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -26 days.
- Sample MMRF_1089_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -26 days.
